Gene-level copy-number profile of tumor specimen MP2PRT-PANWPU-TMP1-A from MP2PRT case MP2PRT-PANWPU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,519 days).
Specimen MP2PRT-PANWPU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fdff774b-f18f-42d9-882c-8b71ea957066.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PANWPU-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/0b95627a-b00f-4004-a879-7980d393c60b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 98; copy number 1: 3,135; copy number 2: 55,665; copy number 3: 12.

Homozygous deletions (total copy number 0; autosomes only): 98 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,326,201–2,352,820, 2 genes (within-gene range 0–2): AL589739.1, AL513477.1.
- chr1:248,906,196–248,937,043, 3 genes: PGBD2, RNU6-1205P, RPL23AP25.
- chr2:242,088,633–242,175,634, 4 genes: LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr3:11,745–54,346, 2 genes: LINC01986, AC066595.1.
- chr3:128,572,000–128,576,086, 1 gene: LINC01565.
- chr5:58,198–58,915, 1 gene: AC113430.1.
- chr5:131,261,321–131,261,607, 1 gene (within-gene range 0–2): AC004777.1.
- chr6:170,615,515–170,738,536, 5 genes: AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:72,103,181–72,104,209, 1 gene (within-gene range 0–2): ABCF2P2.
- chr8:145,047,860–145,066,685, 2 genes: AC139103.1, C8orf33.
- chr9:12,134–89,850, 7 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr12:12,310–38,133, 3 genes: DDX11L8, WASH8P, FAM138D.
- chr12:129,839,928–129,854,944, 2 genes (within-gene range 0–2): AC055717.3, AC055717.1.
- chr13:114,273,828–114,337,626, 5 genes: MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:106,850,885–106,879,812, 6 genes: MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr15:101,922,042–101,979,093, 9 genes: OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr18:80,157,232–80,247,514, 1 gene (within-gene range 0–2): PARD6G.
- chr18:80,183,680–80,202,992, 1 gene: AC139100.1.
- chr19:5,782,960–5,828,324, 4 genes: PRR22, AC011499.1, DUS3L, NRTN.
- chr19:58,543,299–58,605,223, 11 genes: RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr21:44,350,163–44,443,081, 4 genes: TRPM2, TRPM2-AS, AP001065.2, AP001065.1.
- chr21:46,635,595–46,691,226, 3 genes: PRMT2, DSTNP1, RPL23AP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 279. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
